TCGA case TCGA-AD-6901 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b76d1de7-6447-474d-bf67-77e0bb2da73a

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 78 years; Vital status: Dead; Days to death: 682 days (1.9 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 78.2 years (28,579 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 682 days (1.9 years).
   Pathology details: Circumferential resection margin: 1; Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 19; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Days to treatment start: 61 days; Days to treatment end: 214 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 488 days (1.3 years); Days to treatment end: 503 days (1.4 years); Treatment outcome: Progressive Disease; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 79.5 years (29,047 days); Days to diagnosis: 468 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 468 days (1.3 years); Residual disease: RX; Treatment anatomic sites: Other.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Days to follow up: 31 days; Disease response: With Tumor.
- Day 468 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 468 days (1.3 years).
- Days to follow up: 682 days (1.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 5.9 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 69 kg; Height: 170 cm; BMI: 23.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AD-6901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.3; Shortest dimension: 0.3.
  Slide TCGA-AD-6901-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 45; Percent lymphocyte infiltration: 5.
- Sample TCGA-AD-6901-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AD-6901-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 5.9; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment: Pharmaceutical therapy drug name: Xeloda.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 682 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 682 days; disease-free interval: event (new tumor event after initially disease-free), 468 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 468 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AD-6901-01A-11D-1923-01): tumor purity 0.57, ploidy 2.72, whole-genome doublings 1.
